Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8SL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8SL-01B (Primary Tumor).

[page 1 of 2]
PROSTATE AND LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 4 = 8

TERTIARY PATTERN 3

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: 5%

4: 95%

5: ___%

NOT DETERMINED

TUMOR LOCATION

APEX

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

ABSENT

SEMINAL VESICAL INVASION

PRESENT

RIGHT

SURGICAL MARGINS

FREE OF INVASIVE CARCINOMA

LYMPHOVASCULAR INVASION

PRESENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 30%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT OBTURATOR

NUMBER OF NODES IDENTIFIED: 3

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT OBTURATOR

NUMBER OF NODES IDENTIFIED: 2

NUMBER OF NODES INVOLVED BY METASTASIS: 0

RIGHT EXTERNAL ILIAC

NUMBER OF NODES IDENTIFIED: 8

NUMBER OF NODES INVOLVED BY METASTASIS: 1

LEFT EXTERNAL ILIAC

NUMBER OF NODES IDENTIFIED: 4

NUMBER OF NODES INVOLVED BY METASTASIS: 0

RIGHT PARAVESICAL

NUMBER OF NODES IDENTIFIED: 1

NUMBER OF NODES INVOLVED BY METASTASIS: 1

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

4/22/14

[page 2 of 2]
LEFT PARAVESICAL

NUMBER OF NODES IDENTIFIED: _1_

NUMBER OF NODES INVOLVED BY METASTASIS: _1_

DIAMETER OF LARGEST LYMPH NODE METASTASIS: _18_MM

ADDITIONAL PATHOLOGIC FINDINGS

NONE

PATHOLOGICAL STAGING

pT3b

pN1

pMX

Noted		/

Source: NCI Genomic Data Commons file c1a47105-8a60-47c6-b9a6-b824bf8d593a (TCGA-YL-A8SL.561D6EB5-1E61-4134-B6F6-96B1B9A27163.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).